Surgical pathology report (de-identified scan), TCGA case TCGA-66-2766, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2766-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Left lung, among others

Clinical diagnosis and question

Colliquating squamous cell carcinoma of the left upper lobe.

REPORT ON FINDINGS**Macroscopy**

- 1.) Inflated, fixed left lung measuring 17 x 14 cm at the base and up to 28 cm in length, central bronchus resection plane located 3 cm proximal to the bifurcation of the upper lobe bronchus. At the hilus a 2.3 cm mobile node with pale brownish-white section surfaces suggestive of a tumor. Pleural fissure obliterated in middle third, at the junction of segment 3 with segment the parietal pleura shows an extensive 4.7 x 5.5 cm area of adhesion. Under this is a centrally soft, but otherwise soft to moderately solid tumor, max. 1.0 cm in size, pale brownish white at the margin, with a relatively clear and somewhat arcuate demarcation, the main mass being in segments 3 and 2 and adjacent sections of the lingula, extending to the pleura in the region of the adhesion and involvement of some nodes up to 2.5 cm in size, especially at central sites, extending here right up to the hilar resection surface. Narrowing of proximal upper lobe segmental bronchi by the tumor. Tumor spread to the pleural fissure, lower lobe shows no macroscopic infiltration. Parenchyma in the tumor environment and peripherally especially in segment 3 partly diffuse, partly patchy induration and of brownish-yellow color. Rest of parenchyma especially in the subpleural region shows slight rarefaction in parts, accentuation of apical lesions in segment 1, with lacunae or lacuna systems up to 0.5 cm here. In the lower lobe at the branch into the bronchi of the basal group two grayish-black nodes up to 0.6 cm.
- 2.) Pleural tissue from repeat resection: flat or membranous tissue measuring 6.5 x 4 cm and up to 0.2 cm thick. Surface partly smooth, partly rough.
- 3.) Hilar LN (station 10) left: 1 cm lesioned grayish-black node.
- 4.) Pulmonary ligament LN (station 9) 1.5 cm fatty tissue with two nodes, 0.8 and 0.5 cm in size.
- 5.) Paraesophageal LN (station 8) left: 1 cm node,
- 6.) Subcarinal LN (station 7): 1.2 cm node with some surrounding tissue.
- 7.) Subaortic LN (aortopulmonary window) (station 5): two nodes with some surrounding tissue, 2.2 and 1.2 cm in size.
- 8.) Low paratracheal LN (station 4) left: two lesioned grayish-black nodes or node parts, 1.4 and 1.3 cm in size, the larger on the section surfaces with 0.3 cm hard yellowish area.
- 9.) Prevascular and retrotracheal LN (station 3) upper lobe vein: 1.2 cm node with some surrounding tissue.
- 10.) Hilar LN (station 10) right: 2 cm node.
- 11.) Paraesophageal LN (station 8) right: two lesioned nodes, 1.6 and 1 cm in size.
- 12.) Low paratracheal LN (station 4) right: 1.8 cm lesioned node or node part. On the section surfaces 0.3 cm hard yellowish area.

[page 2 of 2]
Examined:

1.) 2 sections of tumor with remaining parenchyma (partly with narrowed bronchial branches), with pleural fissure, 2 sections of tumor with pleura or pleural adhesion., 2 sections of involved nodes with hilar resection surface (color-marked), S3 peripheral, lower lobe node, S1 apical, central bronchus resection plane and resection margins of vessels, hilar nodes (lamellated),

2.) All material (lamellated),

3.) - 12.) All material (in 4. nodes isolated, in 6., 8., 9. + 12. nodes halved in each case, in 7. larger preparation, in 10. nodes multi-segmented),

22 blocks, partly Elastica-van Gieson, PAS, diastase-PAS, decalcification.

Microscopy

Description of histological and cytological findings omitted for capacity reasons.

EVALUATION

Primary diagnosis/diagnoses:

Large, central to peripheral bronchopulmonary, histologically poorly differentiated, large-cell and polymorphocellular, nonkeratinizing squamous cell carcinoma of the upper lobe of the left lung. TNM classification according to this picture pT2 pN2 V1 R0, stage MA. C 34.1; M 8070/3; 3.

Secondary diagnosis/diagnoses:

Tumor necrosis varying in extent with the formation of a lacuna. Chronic resorptive and organizing pneumonia in the tumor environment and S3 periphery. Emphysematous stromal remodeling of lung parenchyma with formation of small subpleural cysts in the apex. Suspected respiratory bronchiolitis. Pleural adhesion zones and chronic fibrosing parietal pleuritis (sample 2.)). Lymph nodes with reactive follicular hyperplasia in some cases (e.g. samples 6.), 8.) and 12.)), in some cases sinus enlargement and an overall rather minor anthracotic pigment deposit.

Remark/addendum:

The main tumor mass lies in segments 3 and 2. Since the central segmental bronchi are tumor-free, it appears to be a primarily peripheral carcinoma of the lung, which has invaded the pleura of the pleural fissure and the adhesion zone, although at the latter site the tumor manifestation appears confined to the visceral layer. Most lymph node metastases, some of which are rather large, are found in the hilus region. A micro-metastasis is detected in sample. 8.), which explains the nodal classification pN2.

Source: NCI Genomic Data Commons file 1ceaca63-c497-45ca-91a7-01b35e289597 (TCGA-66-2766.D210F986-D5A2-4490-87A4-E14564A6D0FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).